Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A3QE, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A3QE-01A (Primary Tumor).

Procurement Date: Laterality:

Path Report: CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy, bilateral salpingo-oophorectomy

Tumor site: Cervix

Tumor size: 3 x 2 x 2 cm

Histologic type: Squamous cell carcinoma, large cell, non-keratinizing

Histologic grade: Moderately differentiated

Tumor extent: Limited to endometrium

Lymph nodes: 0/14 positive for metastasis (Pelvic 0/14)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Extent of myometrial invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
squamous cell carcinoma,
large cell, non keratinizing
807213
site: cervix, NOS
C53.9

2.28.12
RD

Source: NCI Genomic Data Commons file 4efdd08d-7f79-4716-bed3-db637dd83aca (TCGA-EA-A3QE.E3358197-B104-4672-863F-8BE50488B2D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).